Somatic mutation profile of tumor specimen TCGA-BQ-7058-01A (aliquot TCGA-BQ-7058-01A-11D-1961-08) from TCGA case TCGA-BQ-7058, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 81.7 years (29,856 days).
Specimen TCGA-BQ-7058-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d0382d1-4cc7-4352-aa37-f22633010860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7058-11A (Solid Tissue Normal), aliquot TCGA-BQ-7058-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03700c01-e297-490b-b6b6-ece4d56ec70f

The open-access MAF lists 67 somatic variants for this specimen: 55 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 9, Frame Shift Del 7, Nonsense Mutation 3, Frame Shift Ins 2, 3'UTR 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFM | c.1403T>C p.F468S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56919493; called by muse, mutect2, varscan2
- ARHGAP29 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53109976; called by muse, mutect2, varscan2
- B4GALNT3 | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV56751148; called by muse, mutect2, varscan2
- BCL9 | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52342386; called by muse, varscan2
- BIRC6 | c.9097G>A p.G3033R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70197217; called by muse, mutect2, varscan2
- CARD11 | c.1840T>A p.S614T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV62754666; called by muse, mutect2, varscan2
- CCN3 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV52383436, COSV99422634; called by muse, mutect2, varscan2
- CILP | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV56022868; called by muse, mutect2, varscan2
- COL8A1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV53731508; called by muse, mutect2, varscan2
- COX11 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54802657; called by muse, mutect2, varscan2
- CSN3 | c.93T>A p.H31Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as COSV59243776; called by muse, mutect2
- DCAF1 | c.3396C>A p.N1132K | Missense Mutation (SNP) | VAF 148/180 reads (82%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60041747; called by muse, mutect2, varscan2
- DPF2 | c.814T>C p.Y272H | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52888363; called by muse, mutect2, varscan2
- ECD | c.1070G>C p.R357P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.709); catalogued as COSV100881362, COSV65899059; called by muse, mutect2, varscan2
- FASN | c.6776G>A p.S2259N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60752099; called by muse, mutect2, varscan2
- FBXW9 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV63507862; called by muse, mutect2, varscan2
- HEATR5B | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV51850823, COSV51852479; called by muse, mutect2, varscan2
- HECTD1 | c.4199G>T p.G1400V | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV67944875, COSV67945622; called by muse, mutect2, varscan2
- HERC1 | c.4319C>G p.A1440G | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV71246836, COSV71247918; called by muse, mutect2, varscan2
- KPRP | c.1631G>A p.G544D | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.364); catalogued as COSV64221291; called by muse, mutect2, varscan2
- LEF1 | c.363T>G p.N121K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as COSV54465472; called by muse, mutect2, varscan2
- METTL4 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1485202040, COSV60603184; called by muse, mutect2, varscan2
- MIER1 | c.181-1G>C p.X61_splice (on ENST00000355356 / NM_001077701.3; = p.X78_splice on NM_020948.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV62529710; called by muse, mutect2, varscan2
- NFATC2 | c.878G>C p.G293A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs147035777, COSV65354172; called by muse, mutect2, varscan2
- NLRP3 | c.2413G>T p.D805Y | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV60221788; called by muse, mutect2, varscan2
- OR1S1 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58706592; called by muse, mutect2, varscan2
- OTULINL | c.848T>C p.F283S | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57034013; called by muse, mutect2, varscan2
- PALM | c.893T>G p.V298G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52767268; called by muse, mutect2, varscan2
- PAPPA | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60279944; called by muse, mutect2, varscan2
- PBRM1 | c.4725T>A p.Y1575* (on ENST00000296302 / NM_001366071.2; = p.Y1468* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 62/84 reads (74%) | catalogued as COSV56268209; called by muse, mutect2, varscan2
- PCBP3 | c.662T>G p.F221C | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV68407290; called by muse, mutect2, varscan2
- PCF11 | c.1768A>C p.S590R | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV100019575, COSV53527525, COSV99036186; called by muse, mutect2, varscan2
- PCNX1 | c.338G>T p.R113M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV53091632; called by muse, mutect2, varscan2
- PDIA5 | c.354T>A p.F118L | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60248144; called by muse, mutect2, varscan2
- PIAS4 | c.179A>C p.E60A | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53678588; called by muse, mutect2, varscan2
- PNPLA8 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV57551919, COSV99993441; called by muse, mutect2, varscan2
- PPP1R15A | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs775373103, COSV52338613; called by muse, mutect2, varscan2
- RASEF | c.2166T>G p.N722K | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV64586469; called by muse, mutect2, varscan2
- RYR1 | c.5309C>T p.S1770L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs398123472, COSV62093143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9A3R1 | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV52852804; called by muse, mutect2, varscan2
- SPTBN2 | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV59449365; called by muse, mutect2, varscan2
- SRL | c.495T>G p.F165L | Missense Mutation (SNP) | VAF 144/203 reads (71%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV68423062; called by muse, mutect2, varscan2
- TMTC3 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57123139; called by muse, mutect2, varscan2
- TRIT1 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1166660338, COSV57547629; called by muse, mutect2, varscan2
- USP33 | c.2743G>T p.V915F | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV62468745; called by muse, mutect2, varscan2
- CDH17 | c.1932del p.S645Lfs*3 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- FAM153B | c.197A>T p.Q66L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); called by mutect2, varscan2
- FOXO1 | c.1157_1163del p.S386Lfs*11 | Frame Shift Del (DEL) | VAF 77/193 reads (40%) | called by mutect2, pindel*, varscan2*
- GPRASP1 | c.3576_3577del p.I1192Mfs*10 | Frame Shift Del (DEL) | VAF 42/68 reads (62%) | called by mutect2, pindel, varscan2
- HOXA5 | c.261_267del p.S87Rfs*34 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- LRBA | c.1502del p.L501Cfs*9 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- NID2 | c.3843del p.F1281Lfs*42 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- PPP1R9B | c.1272dup p.Y425Lfs*58 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- RBL2 | c.44del p.P15Lfs*59 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- SETD2 | c.1749dup p.Q584Tfs*6 | Frame Shift Ins (INS) | VAF 58/78 reads (74%) | called by mutect2, varscan2
- AFF1 | c.1467A>T p.S489= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV57118297; called by muse, mutect2, varscan2
- BCL9 | c.454A>C p.R152= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV52342374; called by muse, varscan2
- DDX5 | c.372A>G p.G124= | Silent (SNP) | VAF 91/154 reads (59%) | catalogued as COSV56748518; called by muse, mutect2, varscan2
- NID1 | c.1368T>C p.T456= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs564280440, COSV51617579; called by muse, mutect2, varscan2
- NLK | c.783A>G p.L261= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV69408087; called by muse, mutect2, varscan2
- NLRP6 | c.1374G>C p.A458= | Silent (SNP) | VAF 64/173 reads (37%) | catalogued as COSV56458716; called by muse, mutect2, varscan2
- PSG3 | c.453C>A p.I151= | Silent (SNP) | VAF 105/260 reads (40%) | catalogued as COSV59503215; called by muse, mutect2, varscan2
- TXNDC5 | c.897T>G p.T299= | Silent (SNP) | VAF 104/251 reads (41%) | catalogued as COSV65730167; called by muse, mutect2, varscan2
- UNC5D | c.690C>T p.T230= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV54779747, COSV99774896; called by muse, mutect2, varscan2
- ADK | c.*57T>C | 3'UTR (SNP) | VAF 60/165 reads (36%) | catalogued as COSV54202071; called by muse, mutect2, varscan2
- DCHS2 | n.3975G>T | RNA (SNP) | VAF 14/37 reads (38%) | catalogued as rs749864754, COSV61769649; called by muse, varscan2
- PLAU | c.*2G>A | 3'UTR (SNP) | VAF 11/28 reads (39%) | catalogued as COSV101032345; called by muse, mutect2, varscan2
